Somatic mutation profile of tumor specimen SM-JU346 (aliquot 7316UP-2310) from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU346: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d504c275-d5db-419c-90b8-b793991bfaf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105210 (Blood Derived Normal), aliquot 7316UP-1848-1105210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83d62448-c201-4a0b-bb5a-d17af293ec21

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP4 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1170966719, COSV56669709; called by muse, mutect2
- FRAS1 | c.6892A>G p.T2298A | Missense Mutation (SNP) | VAF 16/604 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- FREM1 | c.4113T>G p.L1371= | Silent (SNP) | VAF 17/325 reads (5%) | catalogued as rs1284219939; called by muse, mutect2
- PCDHA7 | c.1509G>A p.A503= | Silent (SNP) | VAF 36/936 reads (4%) | catalogued as COSV65347773; called by muse, mutect2
